Gene-level copy-number profile of tumor specimen TCGA-UD-AAC4-01A from TCGA case TCGA-UD-AAC4, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 65.6 years (23,949 days).
Specimen TCGA-UD-AAC4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.52cc2fd1-88c4-46f8-99c2-d2f4a6351b36.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UD-AAC4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/367de9e2-518e-49bf-a6d8-c0f408be18c7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,193; copy number 2: 49,114; copy number 3: 1,387; copy number 4: 686; copy number 5: 1,400; copy number 6: 17; copy number 8: 16; copy number 9: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UD-AAC4-01A-11D-A39Q-01): tumor purity 0.6, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,440 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:14,705,076–15,052,276, 7 genes, copy number 9: RPS18P12, AC013248.1, AC005863.1, LINC02096, RPL23AP76, AC005772.1, CDRT7.
- chr17:27,333,241–27,684,144, 17 genes, copy number 6: AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1.
- chr17:29,560,547–29,707,090, 1 gene, copy number 5 (within-gene range 4–5): ABHD15-AS1.
- chr17:29,589,769–34,174,964, 168 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:38,749,360–74,154,212, 1,185 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:28,435,388–30,085,893, 43 genes, copy number 5 (within-gene range 4–5): AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr19:42,268,537–42,670,816, 19 genes, copy number 5–8: CIC, PAFAH1B3, PRR19, TMEM145, MEGF8, MIR8077, CNFN, LIPE-AS1, LIPE, AC011497.1, CXCL17, RNU4-60P, AC011497.2, CEACAM1, CEACAMP2, CEACAM8, CEACAMP1, CEACAMP5, RPS10P28.

Autosomal genes at a single copy (total copy number 1): 4,806. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
